Somatic mutation profile of tumor specimen 46c73531-f531-4ec3-97fe-b39d9d (aliquot 46c73531-f531-4ec3-97fe-b39d9d_D6) from CPTAC case 17OV014, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 46c73531-f531-4ec3-97fe-b39d9d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c9218a6-5110-429d-84e5-e5eef8749899.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 61688352-1332-4b68-8412-b53178 (Blood Derived Normal), aliquot 61688352-1332-4b68-8412-b53178_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a74523d3-cb2d-4148-add1-94d79f198cad

The open-access MAF lists 72 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Intron 6, RNA 3, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1, Splice Region 1, 5'UTR 1, 3'Flank 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 246/490 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRL2 | c.4188del p.S1397Pfs*38 (on ENST00000370717 / NM_001366005.1; = p.S1341Pfs*38 on NM_012302.4) | Frame Shift Del (DEL) | VAF 76/297 reads (26%) | catalogued as COSV54675255; called by mutect2, pindel, varscan2
- DNAH10 | c.1298G>A p.R433Q (on ENST00000409039; = p.R372Q on NM_207437.3) | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as rs749515621, COSV68991430; called by muse, mutect2, varscan2
- FREM2 | c.4474A>C p.I1492L | Missense Mutation (SNP) | VAF 128/488 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV54827394; called by mutect2, varscan2
- FZD8 | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753013402; called by muse, mutect2, varscan2
- KEAP1 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as rs200652594, COSV50375276; called by muse, varscan2
- NOL4L | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1441782039; called by muse, varscan2
- NOTCH1 | c.5620G>A p.V1874I | Missense Mutation (SNP) | VAF 149/538 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs760213571; called by muse, mutect2, varscan2
- OR6C68 | c.854C>G p.S285C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV65563120, COSV65564181; called by muse, mutect2, varscan2
- PRAG1 | c.3931G>A p.D1311N | Missense Mutation (SNP) | VAF 194/564 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs898049465, COSV58164109; called by muse, mutect2, varscan2
- RPL10L | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 135/522 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV53560119; called by muse, mutect2, varscan2
- RYR1 | c.5453C>T p.A1818V | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs1274823763, COSV62092082, COSV62113411; called by muse, mutect2, varscan2
- SERTAD1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 11/344 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1331729545, COSV63596523; called by muse, mutect2
- SLC45A4 | c.1358G>A p.R453H (on ENST00000517878 / NM_001286646.2; = p.R402H on NM_001080431.2) | Missense Mutation (SNP) | VAF 255/1121 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs748393317, COSV50132972; called by muse, mutect2, varscan2
- SMAD3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 172/931 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs1180268708, CD1110159; called by muse, mutect2, varscan2
- SOCS2 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 90/401 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61391940, COSV61392211; called by muse, mutect2, varscan2
- USP7 | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1343557524; called by muse, mutect2, varscan2
- ZFAND6 | c.241A>T p.T81S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99929033; called by muse, mutect2, varscan2
- ZNF236 | c.3992G>C p.G1331A | Missense Mutation (SNP) | VAF 89/315 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV53492147; called by muse, mutect2, varscan2
- ZNF516 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 186/603 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as rs930040861; called by muse, mutect2, varscan2
- ABCA8 | c.1957C>G p.L653V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD60 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CA3 | c.331G>T p.G111* | Nonsense Mutation (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2
- CCDC148 | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- CHD7 | c.5240A>G p.Y1747C | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- COL20A1 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COLGALT2 | c.1635G>C p.R545S | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP4F22 | c.1292T>C p.I431T | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- DLK1 | c.380A>T p.K127M | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DNAJC6 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GPATCH3 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 131/440 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEXA | c.459+1G>A p.X153_splice | Splice Site (SNP) | VAF 39/153 reads (25%) | called by muse, mutect2, varscan2
- KBTBD3 | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 70/350 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR3DL1 | c.1198C>G p.Q400E | Missense Mutation (SNP) | VAF 189/283 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT35 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 269/595 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- LRP2 | c.8314G>T p.E2772* | Nonsense Mutation (SNP) | VAF 80/310 reads (26%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRPH2 | c.794T>A p.M265K | Missense Mutation (SNP) | VAF 148/429 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SCIN | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- SRD5A3 | c.696A>C p.A232= | Splice Region (SNP) | VAF 88/202 reads (44%) | called by muse, mutect2, varscan2
- SUPT20HL1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 136/514 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SVEP1 | c.9152A>T p.Q3051L | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TAS2R31 | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZMAT1 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BBOF1 | c.948C>T p.H316= | Silent (SNP) | VAF 40/149 reads (27%) | catalogued as rs750931918, COSV67455760; called by muse, mutect2, varscan2
- CA3 | c.333A>G p.G111= | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as COSV99570538; called by muse, mutect2
- CEP152 | c.1104G>A p.K368= | Silent (SNP) | VAF 147/541 reads (27%) | catalogued as COSV57861628; called by muse, mutect2, varscan2
- CNGB1 | c.2628C>T p.I876= | Silent (SNP) | VAF 124/406 reads (31%) | catalogued as rs1209021925; called by muse, mutect2, varscan2
- EPHB6 | c.1812T>A p.A604= | Silent (SNP) | VAF 378/1479 reads (26%) | called by muse, mutect2, varscan2
- FBLN2 | c.2493G>A p.V831= | Silent (SNP) | VAF 58/245 reads (24%) | called by muse, mutect2
- GABPB1 | c.576C>T p.N192= | Silent (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2, varscan2
- GON4L | c.57C>G p.G19= | Silent (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- GRPR | c.957C>A p.P319= | Silent (SNP) | VAF 114/472 reads (24%) | called by muse, mutect2, varscan2
- HEPH | c.2496C>T p.R832= (on ENST00000343002; = p.R565= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- MSTN | c.489C>T p.V163= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs563747575, COSV53621678; called by muse, mutect2, varscan2
- MYO16 | c.1470T>C p.P490= | Silent (SNP) | VAF 16/128 reads (13%) | called by mutect2, varscan2
- PNPLA4 | c.543C>A p.I181= | Silent (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- RP1L1 | c.3660C>T p.D1220= | Silent (SNP) | VAF 428/723 reads (59%) | catalogued as rs375441998; ClinVar: benign; called by mutect2, varscan2
- STX7 | c.750G>T p.A250= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- AC009039.2 | chr16:52084373 A>G | 5'Flank (SNP) | VAF 53/256 reads (21%) | called by muse, mutect2, varscan2
- AICDA | c.427+40C>G | Intron (SNP) | VAF 74/204 reads (36%) | called by muse, mutect2, varscan2
- CASZ1 | c.506-61G>A | Intron (SNP) | VAF 65/193 reads (34%) | called by muse, mutect2, varscan2
- CHIT1 | c.*774C>T | 3'UTR (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- CLK3 | c.1740+125G>A | Intron (SNP) | VAF 73/199 reads (37%) | catalogued as rs775092959; called by muse, mutect2, varscan2
- COG3 | c.-2C>T | 5'UTR (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- DIO3OS | chr14:101552426 G>T | 3'Flank (SNP) | VAF 73/358 reads (20%) | called by muse, mutect2, varscan2
- ERCC6 | c.2382+835A>G | Intron (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- KCNAB1 | c.276-129677A>C | Intron (SNP) | VAF 69/562 reads (12%) | called by muse, mutect2, varscan2
- LINC01159 | n.280T>C | RNA (SNP) | VAF 50/194 reads (26%) | called by muse, mutect2, varscan2
- MUC19 | n.5778C>G | RNA (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- NUP210P1 | n.277G>T | RNA (SNP) | VAF 34/344 reads (10%) | called by muse, mutect2
- TRIM17 | c.883+16G>C | Intron (SNP) | VAF 227/501 reads (45%) | called by muse, mutect2, varscan2
